CCDI case PBCAIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a14c8811-26d3-49da-85d7-6e7a8d342ec3

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,747 days).

Biospecimens (3 samples)
- Sample 0DMBLK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBM4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBMC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
